Gene-level copy-number profile of tumor specimen TCGA-92-7341-01A from TCGA case TCGA-92-7341, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.6 years (26,134 days).
Specimen TCGA-92-7341-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.05b44e46-fb2e-46f8-b319-1a82620dc805.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-92-7341-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/99a8bdf8-247e-44dd-90de-df5dd941ed6c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 473; copy number 2: 2,122; copy number 3: 9,307; copy number 4: 17,126; copy number 5: 4,201; copy number 6: 8,285; copy number 7: 6,399; copy number 8: 7,550; copy number 9: 1,588; copy number 10: 909; copy number 11: 544; copy number 12: 623; copy number 13: 92; copy number 14: 147; copy number 15: 22; copy number 16: 54; copy number 17: 59; copy number 19: 61; copy number 21: 6; copy number 22: 66; copy number 25: 24; copy number 30: 23; copy number 31: 68; copy number 33: 5; copy number 35: 35; copy number 49: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-92-7341-01A-31D-2041-01): tumor purity 0.51, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:76,074,746–77,250,826, 14 genes (within-gene range 0–4): ST6GALNAC3, AC103592.1, AC104458.1, TPI1P1, RNU6-161P, LINC02567, ST6GALNAC5, MIR7156, AL035409.2, AL035409.1, PIGK, AC113935.1, AC093433.1, AC093433.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,335 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:78,889,764–80,051,404, 7 genes, copy number 9–15: ADGRL4, PSAT1P3, AL353651.2, AL353651.1, LINC02792, ADH5P2, AC099671.1.
- chr1:121,396,754–121,580,524, 6 genes, copy number 21: LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr2:41,716,133–78,290,469, 663 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr2:172,084,740–203,873,965, 528 genes, copy number 10–17 (broad region; genes not listed).
- chr3:99,215,224–99,799,226, 6 genes, copy number 17 (within-gene range 3–17): ACTG1P13, AC107297.1, AC078828.1, AC107029.1, AC107029.2, COL8A1.
- chr3:108,589,705–109,118,134, 7 genes, copy number 14 (within-gene range 3–14): DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3.
- chr3:157,543,246–158,545,730, 9 genes, copy number 9 (within-gene range 7–9): SLC66A1L, AC084212.1, AC079943.2, RN7SKP46, AC079943.1, SHOX2, RSRC1, AC074276.1, AC074276.2.
- chr3:158,869,898–161,503,942, 42 genes, copy number 11: AC092999.1, IQCJ-SCHIP1, IQCJ, MIR3919, AC063955.1, AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1, IL12A-AS1, IL12A, LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1.
- chr3:163,026,396–163,479,500, 5 genes, copy number 33: AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P.
- chr3:164,171,471–190,716,399, 441 genes, copy number 11–49 (broad region; genes not listed).
- chr3:191,199,241–198,222,513, 194 genes, copy number 9–16 (broad region; genes not listed).
- chr4:186,426,546–190,092,279, 70 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr5:58,198–15,496,353, 276 genes, copy number 9 (broad region; genes not listed).
- chr5:15,602,189–15,619,109, 1 gene, copy number 9: CTD-2350J17.1.
- chr5:17,065,598–45,895,970, 415 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr6:61,240,898–65,707,226, 32 genes, copy number 14: AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr6:72,522,641–74,004,812, 38 genes, copy number 11–16: FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7.
- chr7:38,239,580–38,932,394, 29 genes, copy number 9 (within-gene range 7–9): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1, AMPH, RN7SL83P, KRT8P20, FAM183BP, VPS41.
- chr7:42,794,906–44,503,879, 55 genes, copy number 11: TCP1P1, AC010132.1, AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32, AC005537.1, Y_RNA, HECW1, HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P, AC004692.2, AC004692.1, LUARIS, STK17A, COA1, BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P.
- chr7:54,330,670–63,176,019, 163 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr11:48,464,053–48,628,493, 11 genes, copy number 16: OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P.
- chr11:69,147,228–74,979,033, 203 genes, copy number 11–19 (within-gene range 4–19) (broad region; genes not listed).
- chr12:23,529,504–24,562,544, 1 gene, copy number 11 (within-gene range 7–11): SOX5.
- chr12:24,212,421–25,874,079, 35 genes, copy number 11: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302.
- chr14:18,333,726–21,511,342, 188 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr14:26,599,755–28,968,400, 23 genes, copy number 11–15 (within-gene range 5–15): AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1.
- chr16:58,733,910–65,938,453, 57 genes, copy number 10: AC106793.1, RNU6-1155P, RN7SL143P, GEMIN8P2, RPL12P36, AC092378.1, Metazoa_SRP, RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1.
- chr16:73,386,771–84,042,795, 217 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr19:27,638,483–42,652,355, 601 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr20:32,631,625–33,044,047, 12 genes, copy number 9 (within-gene range 8–9): C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6.

Autosomal genes at a single copy (total copy number 1): 465. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
